Surgical pathology report (de-identified scan), TCGA case TCGA-HB-A2OT, project TCGA-SARC (Sarcoma), tissue source site University of North Carolina, specimen TCGA-HB-A2OT-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Review of History:		

Diagnosis:

Soft tissue mass, right thigh, re-excision

Tumor histologic type: residual pleomorphic sarcoma, undifferentiated

Tumor microscopic size (largest dimension): 9 mm, present adjacent to prior biopsy site cyst wall

Tumor grade (FNCLCC system): Grade 3

ICD-0-3
Sarcoma, undifferentiated [pleomorphic]
8805/3

Percent necrosis: not applicable

Site: thigh, NOS C49.2
(sarcoma)

Lymph nodes: none present in this specimen

lw
8/24/11

Surgical margins: Free of tumor. Closest margin is superior deep, where tumor is 3 mm from the inked deep margin at the superior aspect of this specimen.

Clinical History:

The patient is a -year-old female with a clinical diagnosis of a right thigh sarcoma. The patient received a re-excision of the right thigh sarcoma.

Gross Description:

Specimen fixation: Formalin

Specimen received: Re-excision

Anatomic site: Right thigh

Dimensions: 13.0 cm in superior to inferior direction, 6.0 cm in medial to lateral direction, 7.5 cm in anterior to posterior direction.

Orientation: Short stitch = superior, long stitch = lateral;
Inking: lateral/blue, medial/yellow, superior/red, inferior/green, deep/black.

Tumor location: N/A

[page 2 of 2]
Tumor dimensions: 7.0 x 5.0 x 2.0 cm; this measurement is the measurement of the cystic space. There are no cystic contents. There is dark brown material located along the lining of the cyst

Estimation of tumor necrosis: Much of the tumor has been replaced by a large cystic space that contains dark brown debris.

Growth pattern: Well-circumscribed and encapsulated

Surgical margins: Negative; the cystic space is located 1.6 cm away from the red inked superior margin, directly adjacent to and 2.0 cm away from the green inked inferior margin, 0.2 cm away from the yellow inked medial margin, 1.0 cm away from the black inked deep margin, 1.0 cm away from the blue inked lateral margin, and 2.0 cm away from the superficial skin.

Other unusual features: None

Tissue submitted for special investigations: The container is marked . . .

Digital photograph taken: No

Block Summary:

Inking: lateral/blue, medial/yellow, superior/red, inferior/green, deep/black

A1 - Superior margin

A2 - Inferior margin

A3 - Medial margin

A4 - Deep margin

A5 - Lateral margin

A6-A7 - Superior margin (skin ellipse measured 9.3 x 1.2 cm)

A8-A10 - Additional representative sections of cyst wall

Source: NCI Genomic Data Commons file ab1a4fd2-28f3-44fe-a778-82e0b8c2909c (TCGA-HB-A2OT.76E7BA86-B2DF-4DCA-BEDA-7F6BFC695314.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).